FM case AD15476 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/09dbeabf-0895-49f7-9c4d-7fe55bf1a3ea

Male, 51.0 years: Melanoma, NOS (ICD-O-3 8720/3) of the skin; primary biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 43% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
